Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A76Y, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A76Y-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN:
Ref Physician:

SPECIMEN INFORMATION

Collected:

Accession #:

Received:

Acct / Reg #:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. uterus, hysterectomy:

Tumor Characteristics:

1. Histologic type: Leiomyosarcoma.
2. Histologic grade: High grade.
3. Tumor site: Myometrium.
4. Tumor size: 10.0 x 9.0 x 8.5 CM.
5. Macroscopic extent of tumor: Tumor confined to myometrium.
6. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Margins uninvolved: Uterine serosa, bilateral parametria.
2. Margins involved: None.

Other:

1. Other significant findings: Endometrium without evidence of malignancy. Frozen section diagnosis confirmed.
2. pTNM stage: pT1bN0 (FIGO IB).

B. cervix, excision:

Negative for malignancy.

C. right external iliac lymph nodes, excision:

7 lymph nodes, negative for metastatic disease.

D. right obturator lymph nodes, excision:

4 lymph nodes, negative for metastatic disease.

E. right common and iliac lymph nodes, excision:

6 lymph nodes, negative for metastatic disease.

F. left external iliac lymph nodes, excision:

3 lymph nodes, negative for metastatic disease.

G. left obturator lymph nodes, excision:

One lymph node, negative for metastatic disease.

H. left common and aortic lymph nodes, excision:

3 lymph nodes, negative for metastatic disease.

I. omentum, excision:

Negative for malignancy.

Comment:

Sections through the uterine mass show tumor with high grade nuclear features, foci of coagulative tumor necrosis and mitotic activity ranging from 5-10 per high powered field. These findings are consistent with leiomyosarcoma.

CLINICAL HISTORY

CLINICAL HISTORY:

Preoperative Diagnosis: Uterine mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Uterine fundus.
- B. Cervix
- C. Right external iliac lymph node
- D. Right obturator lymph node
- E. Right common iliac lymph node
- F. Right external iliac lymph node
- G. Left obturator lymph node
- H. Left common aortic lymph node
- I. Omentum

ICD-O.3

Leiomyosarcoma NOS
8890/3

C64.2

Site: Uterus NOS
path C55.9

Myometrium C54.2

JD 8/19/13

[page 2 of 2]
SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is received in formalin labeled uterine fundus. The specimen consists of a uterine fundus that measures 12.0 x 12.0 x 9.0 cm and weighs 794 grams. The serosal surface of the uterus is gray tan to brown tan. Sections from the parametrium have been taken. There is a portion of the upper endocervical canal lower uterine segment area attached measuring 2.5 cm. The uterus is bisected. The endometrial cavity measures 4.0 cm in length and 6.0 cm from cornu to cornu. The lining measures 0.2 cm and is red tan hemorrhagic. Endometrial lesions are not identified. There is a submucosal light tan whorled mass that measures 10.0 x 9.0 x 8.5 cm. On sectioning the cut surface has a gray tan whorled appearance. On sectioning there is no necrosis grossly identified. There is a focal area of hemorrhage. A representative section was examined at the time of surgery. The remainder of the myometrium is gray tan and hemorrhagic. There are no other lesions identified. Received with the specimen are three cassettes, one yellow, one green, one blue labeled Representative sections are submitted in cassettes labeled as follows: Frozen section block 1; anterior endometrium myometrium in block 2; posterior endometrium myometrium in block 3; additional sections from the mass in blocks 4-13; area of the resected margin in block 14; left parametrium block 15; right parametrium block 16.

B. The second container B is received in formalin labeled cervix. The specimen consists of a cervix measuring 4.8 cm in length and 3.5 cm in diameter and has a 1.5 cm slit like patent os. The ectocervix is gray tan to pink tan with slight hemorrhage. On sectioning, the endocervical canal is light tan with normal appearing mucosal folds. There are multiple cysts containing mucus measuring up to 0.3 cm. Representative sections are submitted in two cassettes labeled and B2.

C. The third container C is received in formalin labeled right external iliac node. The specimen consists of a portion of fibroadipose tissue that measures 6.0 x 6.5 x 2.0 cm. Sectioning reveals seven possible lymph nodes that measure from 0.8 to 1.8 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: Four possible nodes block 1; one possible node bisected block 2; one possible node bisected block 3; one possible node bisected in block 4 and 5.

D. The fourth container D is received in formalin labeled right obturator. The specimen consists of a portion of fibroadipose tissue measuring 6.0 x 3.5 x 5 cm. Sectioning reveals four possible lymph nodes that measure from 0.7 to 2.5 cm. The lymph nodes are submitted in cassettes labeled as follows: One possible node block 1; one possible node bisected block 2; one possible node bisected in block 3; one possible node trisected in blocks 4-6.

E. The fifth container E is received in formalin labeled right common aortic node. The specimen consists of a portion of fibroadipose tissue, 5.2 x 4.5 x 1.5 cm. Sectioning reveals six possible lymph nodes that measure from 0.5 to 1.8 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: Two possible nodes block 1; three possible nodes block 2; one possible node bisected in block 3 and 4; one possible node bisected in block 5.

F. The sixth container F is received in formalin labeled left external iliac lymph node. The specimen consists of a portion of fibroadipose tissue, 5.5 x 4.5 x 1.8 cm. Sectioning reveals three possible lymph nodes that measure from 1.8 to 2.2 cm. The lymph nodes are submitted in cassettes labeled as follows: One possible node sectioned in blocks 1 and 2; one possible node trisected in blocks 3-5; one possible node trisected in blocks 6 and 7.

G. The seventh container G is received in formalin labeled left obturator lymph node. The specimen consists of a portion of fibroadipose tissue measuring 7.0 x 3.5 x 1.5 cm. Sectioning reveals a single node showing marked fatty infiltration that measures 6.5 x 2.0 x 1.5 cm. The lymph node is sectioned and submitted in six cassettes labeled.

H. The eighth container H is received in formalin labeled left common and aortic lymph node. The specimen consists of a portion of fibroadipose tissue that measures 5.5 x 5.0 x 1.5 cm. Sectioning reveals three possible lymph nodes that measure from 0.7 to 1.8 cm. The lymph nodes are submitted in cassettes labeled as follows: Two possible nodes block 1; two possible nodes block 2; one possible node trisected in block 3; one possible node bisected in block 4; one possible node bisected in block 5; one possible node bisected in block 6 and 7.

I. The ninth container I is received in formalin labeled omentum. The specimen consists of a piece of yellow tan robust fibroadipose omentum tissue that measures 32 x 9 x 1 cm. On sectioning, there are no nodules or lesions identified. Representative sections are submitted in four

HPAAs Discrepancy		☒
Case is (Co)diagnosed		☒
Reviewed		☒

hw 8/2/13

Signature: [Signature]

Date: 8/2/13

INTRA-OPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS: Atypical spindle cell proliferation, pt

Source: NCI Genomic Data Commons file 6338c407-3e25-4989-8cf2-f1d72d135ade (TCGA-FX-A76Y.324C9E7A-8944-45BA-8F8E-A27088405889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).